Somatic mutation profile of tumor specimen TCGA-HV-AA8V-01A (aliquot TCGA-HV-AA8V-01A-11D-A40W-08) from TCGA case TCGA-HV-AA8V, project TCGA-PAAD (Pancreatic Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Head of pancreas; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 50.3 years (18,357 days).
Specimen TCGA-HV-AA8V-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cbe93f81-556d-43ca-8aa8-242955b77990.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HV-AA8V-10A (Blood Derived Normal), aliquot TCGA-HV-AA8V-10A-01D-A40W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e293aef1-3073-4c93-9d3f-a47a937644a3

The open-access MAF lists 34 somatic variants for this specimen: 25 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GNAS | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 26/336 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as rs11554273, COSV55670339, COSV55670675, COSV55677163; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 21/233 reads (9%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- SMAD4 | c.353C>T p.A118V | Missense Mutation (SNP) | VAF 22/291 reads (8%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV61684095, COSV61696676; called by muse, mutect2
- TP53 | c.452C>G p.P151R | Missense Mutation (SNP) | VAF 22/288 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2
- ADGRA2 | c.1868C>T p.P623L | Missense Mutation (SNP) | VAF 69/1021 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.173); catalogued as rs370919357; called by muse, mutect2
- ADGRB1 | c.3155G>A p.R1052H | Missense Mutation (SNP) | VAF 30/219 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as rs200093247, COSV100030093; called by mutect2, varscan2
- BEND3 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 8/140 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.91); catalogued as rs1213543267, COSV100944649; called by muse, mutect2
- BMP5 | c.284A>T p.E95V | Missense Mutation (SNP) | VAF 30/548 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.175); catalogued as COSV100896199; called by muse, mutect2
- CALD1 | c.94G>A p.D32N | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100724468; called by muse, mutect2
- CMYA5 | c.11618T>G p.F3873C | Missense Mutation (SNP) | VAF 61/739 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs146960317, COSV101405679; called by muse, mutect2
- DEPDC7 | c.718T>C p.S240P (on ENST00000241051 / NM_001077242.2; = p.S231P on NM_139160.2) | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99572833; called by muse, mutect2
- ENTPD4 | c.923G>T p.G308V | Missense Mutation (SNP) | VAF 47/458 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100652733; called by muse, mutect2, varscan2
- HJURP | c.1946G>T p.S649I | Missense Mutation (SNP) | VAF 28/430 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV100982621; called by muse, mutect2
- IPO7 | c.2476G>A p.D826N | Missense Mutation (SNP) | VAF 14/222 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV101121797; called by muse, mutect2
- IRS1 | c.2569C>T p.R857W | Missense Mutation (SNP) | VAF 34/334 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1327028772, COSV100524798; called by muse, varscan2
- KHSRP | c.1013T>C p.I338T | Missense Mutation (SNP) | VAF 11/184 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV101231218; called by muse, mutect2
- LRRIQ1 | c.831T>A p.N277K | Missense Mutation (SNP) | VAF 16/281 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV101280654; called by muse, mutect2
- LRRIQ4 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 20/253 reads (8%) | SIFT tolerated (0.82); PolyPhen benign (0.068); catalogued as COSV100540325; called by muse, mutect2
- MAGEB10 | c.326G>T p.G109V | Missense Mutation (SNP) | VAF 12/73 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV100775343; called by muse, mutect2, varscan2
- MAP4K3 | c.1120G>T p.D374Y | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as COSV99810871; called by muse, mutect2
- MED15 | c.1901T>C p.F634S (on ENST00000263205 / NM_001003891.3; = p.F594S on NM_015889.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/765 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99487968; called by muse, mutect2
- MORF4L2 | c.384A>T p.E128D | Missense Mutation (SNP) | VAF 105/830 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as COSV100846388; called by muse, mutect2, varscan2
- PCDHGA5 | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 24/281 reads (9%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); catalogued as COSV54013212; called by muse, mutect2
- PNMA5 | c.863G>A p.R288H | Missense Mutation (SNP) | VAF 26/215 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.477); catalogued as rs782553555, COSV62625985; called by muse, mutect2, varscan2
- UBR4 | c.4900T>C p.S1634P | Missense Mutation (SNP) | VAF 66/766 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.939); catalogued as COSV100921401; called by muse, mutect2
- AADACL3 | c.582C>T p.F194= | Silent (SNP) | VAF 31/404 reads (8%) | catalogued as rs370572357; called by muse, mutect2
- ADAM7 | c.408C>T p.N136= | Silent (SNP) | VAF 26/471 reads (6%) | catalogued as rs143068519; called by muse, mutect2
- ADCY10 | c.3561G>T p.V1187= | Silent (SNP) | VAF 52/717 reads (7%) | catalogued as COSV100897000; called by muse, mutect2
- CADM1 | c.1248C>T p.D416= | Silent (SNP) | VAF 49/657 reads (7%) | catalogued as rs750612978, COSV59005190; called by muse, mutect2
- CLDN23 | c.324G>A p.E108= | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as COSV101093157; called by muse, mutect2
- FBXL6 | c.1056A>T p.G352= | Silent (SNP) | VAF 16/330 reads (5%) | catalogued as COSV100095955; called by muse, mutect2
- GATA2 | c.1332G>A p.P444= | Silent (SNP) | VAF 24/282 reads (9%) | catalogued as rs770768777, COSV62005037; ClinVar: likely benign; called by muse, mutect2
- LRATD2 | c.234G>T p.L78= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV100513633; called by muse, mutect2
- SACM1L | c.459C>T p.F153= | Silent (SNP) | VAF 26/310 reads (8%) | catalogued as rs1270543675, COSV101203784; called by muse, mutect2
